Gene-level copy-number profile of tumor specimen ALCH-B2NQ-TTP1-A from ALCHEMIST case ALCH-B2NQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.6 years (18,487 days).
Specimen ALCH-B2NQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 788e4868-9c80-466c-981e-4366625302cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2NQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/c4a52f3f-a6a9-46fd-8409-59ae925d1d33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 2,931; copy number 2: 54,360; copy number 3: 991; copy number 4: 98; copy number 5: 2; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,645,864–127,652,639, 1 gene (within-gene range 0–1): GPR17.
- chr4:98,025,390–98,049,043, 2 genes (within-gene range 0–2): RPL5P12, DUTP8.
- chr10:94,865,852–94,873,129, 1 gene: CYP2C58P.
- chr15:25,185,631–25,209,999, 14 genes (within-gene range 0–2): SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:21,300,990–21,358,067, 4 genes, copy number 5–13 (within-gene range 2–13): FAM230H, AP000552.2, PPP1R26P5, LINC01651.

Autosomal genes at a single copy (total copy number 1): 1,135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
